Somatic mutation profile of tumor specimen MBCProject_0487_T1_WES (aliquot MBCProject_0487_T1_WES_1) from CMI case MBCProject_0487, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 66.2 years (24,183 days).
Specimen MBCProject_0487_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ddace27-d8d4-4c55-b8f1-fdc922ae5de5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0487_SALIVA (Saliva), aliquot MBCProject_0487_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37723e45-8a98-4c9e-99ee-7dcba49cc3e4

The open-access MAF lists 40 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, 5'UTR 2, Nonsense Mutation 2, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1097C>T p.P366L (on ENST00000447712 / NM_023110.3; = p.P364L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/698 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs121909641, CM063981; ClinVar: risk factor / likely pathogenic; called by muse, mutect2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 20/77 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CACHD1 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1235538167, COSV51557130, COSV51562484; called by muse, mutect2, varscan2
- DNAH1 | c.6254G>A p.R2085K | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs922653981, COSV70233173; called by muse, mutect2
- GOLGA2 | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1178321620; called by muse, mutect2
- ITGAL | c.162C>T p.N54= | Splice Region (SNP) | VAF 40/153 reads (26%) | catalogued as rs1262020524; called by muse, mutect2, varscan2
- MAP2K4 | c.1069A>C p.K357Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV62255607, COSV62258138; called by muse, mutect2, varscan2
- MXRA5 | c.6367G>A p.V2123M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779869276, COSV54254220; called by muse, mutect2, varscan2
- PRRX1 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1409882371; called by muse, mutect2, varscan2
- SEMG2 | c.1454C>T p.T485M | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs138562452, COSV104425365; called by muse, mutect2, varscan2
- TLX3 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 88/569 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV51540742; called by muse, mutect2, varscan2
- ZFHX4 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.077); catalogued as rs747829798, COSV99263442; called by muse, mutect2, varscan2
- ADAM9 | c.1826C>A p.S609* | Nonsense Mutation (SNP) | VAF 50/235 reads (21%) | called by muse, mutect2, varscan2
- BRD2 | c.2199G>C p.K733N | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- BTBD17 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.508); called by muse, mutect2
- DRD1 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 22/359 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HASPIN | c.1025A>T p.H342L | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF13A | c.620G>C p.R207P | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAML1 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- MYO15A | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPR1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2
- PCDHGA7 | c.1433A>G p.D478G | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPL | c.3755G>T p.R1252M | Missense Mutation (SNP) | VAF 111/364 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRICKLE3 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.104); called by muse, mutect2
- SDHA | c.1243A>G p.T415A | Missense Mutation (SNP) | VAF 36/528 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- SLC47A1 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 126/493 reads (26%) | called by muse, varscan2
- VEZF1 | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 38/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF732 | c.1193C>A p.A398D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNRF4 | c.219G>C p.W73C | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- GEMIN5 | c.3549G>T p.L1183= | Silent (SNP) | VAF 23/161 reads (14%) | called by muse, mutect2, varscan2
- IL16 | c.2577C>T p.A859= (on ENST00000302987 / NM_172217.5; = p.A158= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/209 reads (16%) | catalogued as rs1251035249; called by muse, varscan2
- OBSL1 | c.1260C>T p.T420= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV54728830; called by muse, mutect2, varscan2
- PLEKHA2 | c.822G>A p.R274= | Silent (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- SCARA5 | c.489C>T p.T163= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV57276249; called by muse, mutect2, varscan2
- STKLD1 | c.1089G>A p.P363= | Silent (SNP) | VAF 7/145 reads (5%) | catalogued as rs782011615; called by muse, mutect2
- VEZF1 | c.642G>A p.K214= | Silent (SNP) | VAF 27/155 reads (17%) | called by muse, varscan2
- GLUD1 | c.-33C>T | 5'UTR (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- RPL5 | c.*48G>A | 3'UTR (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- STAR | c.-2C>T | 5'UTR (SNP) | VAF 36/1228 reads (3%) | called by muse, mutect2
- USP22 | chr17:21043710 G>C | 5'Flank (SNP) | VAF 134/418 reads (32%) | called by muse, varscan2
